Somatic mutation profile of tumor specimen TCGA-CD-5803-01A (aliquot TCGA-CD-5803-01A-11D-1600-08) from TCGA case TCGA-CD-5803, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 78.3 years (28,608 days).
Specimen TCGA-CD-5803-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29515327-a526-413f-9501-571fc22bacd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-5803-10A (Blood Derived Normal), aliquot TCGA-CD-5803-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87214086-c2a5-4f5a-a0c8-fdb2339a648d

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 25, Silent 8, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT2 | c.647A>G p.E216G | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV51488830; called by muse, mutect2, varscan2
- ARID1A | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 18/147 reads (12%) | catalogued as COSV61377198, COSV61384452, COSV61387404; called by muse, mutect2, varscan2
- AVIL | c.2322G>C p.E774D | Missense Mutation (SNP) | VAF 32/377 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs766006295, COSV57683009; called by muse, mutect2
- CABP1 | c.751G>T p.G251C (on ENST00000316803 / NM_001033677.1; = p.G48C on NM_004276.5) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56459758; called by muse, mutect2
- CCDC114 | c.1038G>T p.L346F | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV59557858; called by muse, mutect2, varscan2
- CHRNA3 | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV100468654; called by muse, mutect2
- CNR1 | c.660G>T p.R220S | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV62990172; called by muse, mutect2, varscan2
- CNTNAP5 | c.3502G>A p.V1168I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375640846, CM1010519; called by muse, mutect2, varscan2
- COL4A5 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60367458; called by muse, mutect2, varscan2
- FANCD2 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55043366; called by muse, mutect2, varscan2
- KDM3B | c.3013G>C p.E1005Q | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100070095, COSV58687363; called by muse, mutect2, varscan2
- OR2T27 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs757391223, COSV100788324, COSV61281501, COSV61283032; called by muse, mutect2, varscan2
- ORAI2 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); catalogued as rs375636106; called by muse, mutect2, varscan2
- PCDHA8 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as rs1554139566, COSV100969510, COSV65324504, COSV65330213; called by muse, mutect2, varscan2
- PTPRS | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53618187; called by muse, mutect2, varscan2
- PYROXD1 | c.85T>G p.L29V | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV53711003; called by muse, mutect2
- RASA2 | c.1858C>T p.R620W | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748310597, COSV53939082; called by muse, mutect2, varscan2
- SCNN1G | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV55600763, COSV55601264; called by muse, mutect2, varscan2
- SLC22A8 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs749501509, COSV60324683; called by muse, mutect2, varscan2
- SLC6A20 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750113286, COSV62071959, COSV62072121, COSV62072547; called by muse, mutect2, varscan2
- SPATA18 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV54648069; called by muse, mutect2
- SPG11 | c.5984T>C p.L1995P | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55999625; called by muse, mutect2, varscan2
- TLR8 | c.2031G>T p.K677N (on ENST00000218032 / NM_138636.5; = p.K695N on NM_016610.4) | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1232992427, COSV54319542; called by muse, mutect2
- VAV3 | c.1642G>A p.G548R | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.232); catalogued as COSV58388609; called by muse, mutect2
- ZNF461 | c.611A>T p.H204L | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.078); catalogued as COSV64454549; called by muse, mutect2, varscan2
- M6PR | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2
- KDM7A | c.555T>C p.Y185= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as rs368809593; called by muse, mutect2, varscan2
- NLRP14 | c.1170A>T p.T390= | Silent (SNP) | VAF 26/335 reads (8%) | catalogued as COSV55070200; called by muse, mutect2
- NOS1 | c.87A>T p.G29= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV57617882; called by muse, mutect2, varscan2
- OTOL1 | c.1416T>C p.T472= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV60007826; called by muse, mutect2
- PDGFRA | c.2757C>T p.D919= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs1189646004, COSV57268383, COSV57271444; called by muse, mutect2
- SLC5A5 | c.1680G>A p.P560= | Silent (SNP) | VAF 24/224 reads (11%) | catalogued as rs149937279; called by muse, mutect2, varscan2
- WNT8A | c.969G>A p.K323= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV64231526; called by muse, mutect2, varscan2
- ZNF132 | c.531C>T p.D177= | Silent (SNP) | VAF 22/215 reads (10%) | catalogued as rs150467107; called by muse, mutect2, varscan2
